Surgical pathology report (de-identified scan), TCGA case TCGA-61-1903, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-1903-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS:

PART 1: LEFT ADNEXA, LEFT SALPINGO-OOPHORECTOMY -

- A. POORLY DIFFERENTIATED SEROUS PAPILLARY CARCINOMA OF THE LEFT OVARY.
- B. HYDROSALPINX, LEFT.

PART 2: RIGHT ADNEXA, RIGHT SALPINGO-OOPHORECTOMY -

- A. POORLY DIFFERENTIATED SEROUS PAPILLARY CARCINOMA OF THE RIGHT OVARY.
- B. UNREMARKABLE RIGHT FALLOPIAN TUBE.

PART 3: UTERUS WITH CERVIX, (68-GRAMS), TOTAL ABDOMINAL HYSTERECTOMY -

- A. UNREMARKABLE CERVIX.
- B. ATROPHIC ENDOMETRIUM.
- C. UNREMARKABLE MYOMETRIUM.

PART 4: POSTERIOR CUL-DE-SAC, BIOPSY -
NEGATIVE FOR TUMOR.

PART 5: PELVIC SIDEWALL, RIGHT, BIOPSY -
NEGATIVE FOR TUMOR.

PART 6: PERICOLIC GUTTER, RIGHT, BIOPSY -
NEGATIVE FOR TUMOR.

PART 7: LYMPH NODES, RIGHT PELVIC, DISSECTION -
EIGHT LYMPH NODES, NEGATIVE FOR TUMOR (0/8).

PART 8: LYMPH NODES, RIGHT COMMON, DISSECTION -
ONE LYMPH NODE; NEGATIVE FOR TUMOR (0/1).

PART 9: LYMPH NODES, RIGHT PERIAORTIC, DISSECTION -
THREE LYMPH NODES, NEGATIVE FOR TUMOR (0/3).

PART 10: PERICOLIC GUTTER, LEFT, BIOPSY -
NEGATIVE FOR TUMOR.

PART 11: PELVIC PERITONEUM, LEFT, BIOPSY -
NEGATIVE FOR TUMOR.

PART 12: BLADDER, BIOPSY -
NEGATIVE FOR TUMOR.

PART 13: LYMPH NODES, LEFT PELVIC, DISSECTION -
FIVE LYMPH NODES, NEGATIVE FOR TUMOR (0/5).

PART 14: LYMPH NODES, LEFT COMMON PERIAORTIC, DISSECTION -
TWO LYMPH NODES, NEGATIVE FOR TUMOR (0/2).

PART 15: LEFT PARAMETRIUM, BIOPSY -
NEGATIVE FOR TUMOR.

PART 16: OMENTUM, EXCISION -
NEGATIVE FOR TUMOR.

PART 17: RIGHT DIAPHRAGM, BIOPSY -
NEGATIVE FOR TUMOR.

[page 2 of 2]
CASE SYNOPSIS:

SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS

TUMOR LOCATION:	Bilateral
PROCEDURE:	TAH with salpingo-oophorectomy
TUMOR SIZE:	Maximum dimension: 8.0 cm
TUMOR TYPE:	Papillary serous carcinoma
HISTOLOGIC SILVERBERG GRADE:	Poorly differentiated (8-9 pts)
ARCHITECTURAL PATTERN:	Papillary (2)
CYTOLOGIC ATYPIA:	Marked (3)
MITOTIC COUNTS / 10hpf:	> or = 25 (3)
VASCULAR INVASION:	No
TUMOR CAPSULE:	Intact
SURFACE IMPLANTS:	Not present
MALIGNANT CELLS IN ASCITES OR PERITONEAL WASHING:	No
LYMPH NODES EXAMINED:	Total number of lymph nodes examined: 19
LYMPH NODES POSITIVE:	Number of positive lymph nodes, Right: 0 Number of positive lymph nodes, Left: 0
T STAGE, PATHOLOGIC:	pT1b
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pM0
FIGO STAGE:	IB

Source: NCI Genomic Data Commons file 889297d3-4597-49b8-b610-080ab1cbacdd (TCGA-61-1903.879AC4E3-CB0D-4FCB-A51D-8CBC6AD0C4A0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).